Surgical pathology report (de-identified scan), TCGA case TCGA-24-1430, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1430-01A (Primary Tumor).

[page 1 of 4]
CHURCHILL PATHOLOGY REPORT

TCGA-24-1430

Other Related Clinical Data:

DIAGNOSIS: OVARY, RIGHT AND LEFT, BILATERAL OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA (SEE COMMENT)

FALLOPIAN TUBE, RIGHT AND LEFT, BILATERAL SALPINGECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA

APPENDIX, APPENDECTOMY
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

SMALL INTESTINE, PARTIAL RESECTION
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA
- MUCOSAL NECROSIS (SEE COMMENT)

COLON, SEROSAL IMPLANT, BIOPSY
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

OMENTUM, OMENTECTOMY
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

SOFT TISSUE, PORTA HEPATIS MASS, EXCISION
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

LYMPH NODES, EXTERNAL ILIAC, EXCISION
- NO EVIDENCE OF MALIGNANCY IN 5 LYMPH NODES (0/5)
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA IN SOFT TISSUE

URINARY BLADDER, WALL, BIOPSY
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

[page 2 of 4]
[REDACTED]

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By [REDACTED]

Intraoperative Consultation:

FS1: Omentum, mass, biopsy

- "Metastatic adenocarcinoma, consistent with Mullerian origin," by [REDACTED]

[REDACTED] Microscopic Description and Comment: Sections of both ovaries show extensive involvement with a papillary serous adenocarcinoma with associated psammomatous microcalcifications. Tumor also involves the fallopian tubes bilaterally. Metastatic tumor is present diffusely in the omentum and the porta hepatis. Serosal involvement of the appendix is present with penetration of tumor into the muscular layer of the appendix. Metastatic tumor in the form of serosal implants is also present in the colon, small intestine, and urinary bladder. The small intestinal segment shows focal mucosal necrosis, consistent with ischemic necrosis. No metastatic tumor is identified in five lymph nodes in the external iliac tissue. However, focal metastatic papillary serous adenocarcinoma is present within the soft tissue from this region. [REDACTED]

[REDACTED] History: The patient is a [REDACTED] with omental cake. Mullerian primary vs other. History of three to four week complaint of pelvic pain. Operative procedure: Examination under anesthesia, exploratory laparotomy, omentectomy, tumor debulking, appendectomy, small bowel resection.

Specimen(s) Received:

- A: OMENTUM, ROUTINE
- B: RIGHT OVARY, GENERIC AND FALLOPIAN TUBE
- C: LARGE BOWEL NODULE AND SEROUSAL IMPLANT
- D: LEFT OVARY
- E: APPENDIX
- F: SMALL INTESTINE, BIOPSY
- G: PORTAHEPATIS MASS
- H: EXTERNAL ILIAC LYMPH NODE
- I: VESICLE WALL MASS

Gross Description The specimens are received in nine containers, each labeled with the patient's name. The first container is labeled "omentum." and "FS1, X1". It contains a white cassette labeled "FS1". The cassette contains a 1.5 x 1.5 x 0.2 cm piece of tan, rubbery soft tissue. Labeled A1. Additionally, within the container is a mass of omental fat measuring 15 x 11 x 3.5 cm. Much of the omentum has been replaced by multiple firm tumor masses, which have coalesced into a larger tumor mass measuring 15 x 4 x 2.5 cm. The surface of several of the masses have a subtle papillary architecture. Two additional sections labeled A2. Jar 3.

The second container is labeled "R ovary and fallopian tube." It contains a 6 x 4 x 3.2 cm mass of tan to red tissue. The external surface of the ovary and the fallopian tube contains disrupted tissues with fibrinous adhesions, and possible tumor. The anatomy of both the fallopian tube and the ovary is difficult to identify because of the adhesions and possible tumors. Multiple tumor masses are identified, which may be in continuity with each other. One appears to be within or next to the fallopian tube, measuring 1.5 x 0.9 x 1.2 cm. A closely associated nodule appears to be within the paraovarian tissues measuring 1.0

[page 3 of 4]
x 1.0 x 1.2 cm. In addition, within the identifiable ovarian parenchyma itself, there is an area of papillary excrescences, which is exposed to the surface, which may also represent tumor. Labeled B1 - ovary with exposed tumor and adjacent fallopian tube with tumor, B2 - section of ovary and paraovarian tumor; B3 - section of fallopian tube without gross tumor, and second section of ovary with possible tumor; B4 - additional section of tumor possibly within fallopian tube, and adjacent ovary with possible tumor. Jar 1.

The third container is labeled "large bowel nodule and serosal implant." It contains multiple pieces of tissue measuring, in aggregate, 2.0 x 2.0 x 0.1 cm. The largest piece appears to have fat, with a small, 0.6 cm in greatest dimension, firm, white, subserosal nodule. There is a smaller piece of tissue also present containing tissue suspicious for tumor. No orientation of the smaller specimens is possible. Labeled C1 - section of subserosal nodule, and sections of firm tissue suspicious for tumor. Jar 1.

The fourth container is labeled "L ovary." It contains three pieces of irregularly-shaped tissue, which is not grossly identifiable as tube or ovary. The largest piece is 4.5 x 3.0 x 1.5 cm, and has firm, pink-tan tissue, grossly suspicious for tumor. A small amount of adipose tissue is present on the specimen, as well. The surfaces are regular, with a papillary gross appearance. One of the smaller pieces contains tissue which possible represents residual ovary. No fallopian tube is identified. Labeled D1, D2 - sections of tumor; D3 - possible residual ovary. Jar 1.

The fifth container is labeled "appendix." It contains a 5 x 1.5 x 1.5 cm vermiform appendix, with a dark red, tan surface suspicious for tumor. Serial cuts through the appendix reveal an intact appendiceal lumen, with a mass of firm, gray-tan tumor in the adventitia, and focally involving the muscularis of the appendix. Labeled E1 - tumor in adventitia and muscle; E2 - normal-appearing appendix. Jar 1.

The sixth container is labeled "small bowel." It contains an 18 cm in length x 2.0 cm in diameter segment of bowel. The serosa of the bowel is dark brown, and possibly ischemic appearing. The bowel is opened to show green-to-brown mucosa, with an area of possible ischemia measuring approximately 7 cm in length, 6 cm from one of the stapled ends. In addition, there is an area of constriction. Within the mesentery, several areas are suspicious for involvement by tumor, with the largest measuring 1.0 cm in greatest dimension. Labeled F1 - one staple margin; F2 - other staple margin; F3 - two sections from possible ischemic region; F4 - possible tumor implants. Jar 3.

The seventh container is labeled "porta hepatis mass." It contains several fragments of tissue, the largest representing a tumor mass measuring 3.6 x 2.5 x 1.7 cm. The tissue consists entirely of tan, slightly papillary tissue, with an occasional cyst on the surface. On cut section, a solid, tan-white tumor mass is present, with central necrosis. Two sections labeled G1. The remaining pieces of tissue have a similar appearance to the larger piece of tissue. Jar 1.

The eighth container is labeled "R external iliac ln." It contains a 5.0 x 4.0 x 1.0 cm aggregate of fat, and five possible lymph nodes. The largest lymph node measures 3.5 x 1.0 x 1.0 cm. Upon sectioning, this lymph node has multiple small lumens, and may represent a large, fibrovascular cord. Labeled H1 - five lymph nodes; H2 - larger fibrovascular cord in multiple sections. Jar 1.

The ninth container is labeled "vesicle wall mass." It contains a 2.0 x 1.0 x 1.0 cm piece of tan-to-brown tissue, with an identifiable serosal surface. Within the specimen there is a firm, white nodule measuring 0.6 cm in greatest dimension. The specimen is sectioned, and labeled I1. Jar 0.

[page 4 of 4]
[REDACTED]

[REDACTED]

Synopsis SYNOPSIS REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. A neoplasm is PRESENT 2. The HISTOLOGIC DIAGNOSIS is: Serous adenocarcinoma 3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Right and left ovary (synchronous primary tumors) 4. The FIGO GRADE of the tumor is: III 6. Tumor IS identified on the ovarian surface(s). 7 Tumor DOES invade the mesovarium. 8. Tumor DOES invade the adjacent fallopian tube. 9. Tumor DOES invade the pelvic soft tissue. 11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT. 12. Metastatic involvement of the omentum is PRESENT. 13. The maximum dimension of tumor implants outside the true pelvis is 15 cm 14. Metastatic involvement of the uterine serosa CANNOT BE EVALUATED. 15. Metastatic involvement of the endometrium CANNOT BE EVALUATED. 16. Regional lymph node metastases are ABSENT. 17. The total number of regional lymph nodes examined is 5 18. The total number of metastatically-involved regional lymph nodes is 0 Extranodal extension by tumor is NOT APPLICABLE; no nodal metastases are present 19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
T3c	IIIC	

THE REGIONAL LYMPH NODES are classified as: N0 (Nodes are free of metastases)

THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed) 20. The FINAL AJCC/UICC/FIGO STAGE IS: AJCC/UICC/FIGO

IIIC (T3c/N0/M0) or

(Any T/N1/M0) The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file b0a28eb1-1859-4d22-8baf-52ca45ee2001 (TCGA-24-1430.D0F95CED-E33F-4796-A6A4-3030F8E21761.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).